Gene-level copy-number profile of tumor specimen TCGA-30-1856-01A from TCGA case TCGA-30-1856, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.5 years (20,626 days).
Specimen TCGA-30-1856-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.d5d2efba-1f54-4de0-b6f0-69ae40f257f6.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-30-1856-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 394 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ecbd3073-2036-43b1-a6f7-1d9f4ec5caa5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 320; copy number 2: 45,732; copy number 3: 12,271; copy number 4: 1,381; copy number 5: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-30-1856-01A-01D-0577-01): tumor purity 0.89, ploidy 5.09, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:30,028,741–30,085,893, 5 genes, copy number 5: AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.

Autosomal genes at a single copy (total copy number 1): 319. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
